Somatic mutation profile of tumor specimen TCGA-VS-A9UR-01A (aliquot TCGA-VS-A9UR-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 53.9 years (19,688 days).
Specimen TCGA-VS-A9UR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 493e8f07-4c82-49fc-aa46-3145b508ee3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UR-10A (Blood Derived Normal), aliquot TCGA-VS-A9UR-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/facd886e-a4eb-4339-8b92-f8a4a6f2c6d0

The open-access MAF lists 119 somatic variants for this specimen: 85 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 28, Nonsense Mutation 8, Intron 3, Splice Site 3, Frame Shift Del 2, 5'UTR 1, Splice Region 1, RNA 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as rs786204545, COSV100280227; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM7 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99444599; called by muse, mutect2, varscan2
- ADCY1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV52030322; called by muse, mutect2, varscan2
- ADGRV1 | c.14241G>C p.K4747N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV101316269; called by muse, mutect2
- ADORA2A | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs144427027, COSV100418016; called by muse, mutect2, varscan2
- ARCN1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as COSV99873861; called by muse, mutect2, varscan2
- ARHGAP17 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99253839; called by muse, mutect2, varscan2
- B4GALNT3 | c.2285G>C p.R762T | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV99843384; called by muse, mutect2, varscan2
- BRCA2 | c.4009G>A p.D1337N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV101204526; called by muse, mutect2, varscan2
- CAMSAP1 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs1364564763, COSV100410252; called by muse, mutect2, varscan2
- CCDC74B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV100134617; called by muse, mutect2, varscan2
- CD163L1 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100550464; called by muse, mutect2, varscan2
- CDK11B | c.1399A>G p.K467E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100478044; called by muse, mutect2, varscan2
- CEP131 | c.1223A>G p.D408G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV99488736; called by muse, mutect2, varscan2
- CROT | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV100519624; called by muse, mutect2, varscan2
- DHX15 | c.1442G>T p.C481F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100391574; called by muse, mutect2, varscan2
- DOCK2 | c.4858C>T p.R1620* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs142830212, COSV99914245; called by muse, mutect2, varscan2
- EFEMP2 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs57685603, COSV100337340; called by muse, varscan2
- EPHX4 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV100952746; called by muse, varscan2
- FAM47C | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.287); catalogued as rs782370801, COSV100792214, COSV63723394; called by muse, mutect2, varscan2
- FCSK | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1180383871, COSV99851136; called by muse, mutect2, varscan2
- FGF16 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs781914307, COSV71546153; called by muse, mutect2, varscan2
- FZD3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs200012243, COSV99528301; called by muse, mutect2, varscan2
- GCC2 | c.3049G>C p.E1017Q | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100565573; called by muse, mutect2, varscan2
- GMNN | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV100017770; called by muse, mutect2
- GPR20 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as rs964972756, COSV100897376; called by muse, mutect2, varscan2
- GPRASP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100851050; called by muse, mutect2, varscan2
- H3C6 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV64519612; called by muse, mutect2
- HLA-C | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs11547351, COSV100880030, COSV100880740, COSV100880756; called by mutect2, varscan2
- HLA-C | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); catalogued as rs77429690, COSV100880579, COSV66113027; called by muse, varscan2
- HMCN1 | c.5278G>T p.G1760C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99633140; called by muse, mutect2, varscan2
- ITIH5 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV53668734, COSV99905350; called by muse, mutect2
- JMJD1C | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101232446; called by muse, mutect2, varscan2
- KCNQ5 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100570810, COSV100571249; called by muse, mutect2, varscan2
- KIAA1755 | c.1928C>A p.P643Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1385459286, COSV99642421; called by muse, mutect2, varscan2
- KRT40 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100898878; called by muse, mutect2, varscan2
- LCE1A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs749443782, COSV100632109; called by muse, mutect2, varscan2
- LECT2 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1473351443, COSV99191874; called by muse, mutect2
- LMTK2 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV99807362; called by muse, mutect2, varscan2
- LRRC71 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100168821; called by muse, mutect2, varscan2
- LRRCC1 | c.1316G>C p.R439T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100835534, COSV64484182; called by muse, mutect2, varscan2
- LTBP3 | c.3643G>C p.E1215Q (on ENST00000301873 / NM_001130144.3; = p.E1168Q on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99534423; called by mutect2, varscan2
- MAN1A2 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333787966, COSV62977708; called by muse, mutect2, varscan2
- MAP7D3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100286549; called by muse, mutect2, varscan2
- MED13 | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV101181224; called by muse, mutect2, varscan2
- MMP14 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs770606883, COSV100314238; called by muse, mutect2, varscan2
- MPP1 | c.515A>T p.K172I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV101053727; called by muse, mutect2, varscan2
- MPPED1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV100501297; called by muse, mutect2
- MRPL4 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99460215; called by muse, mutect2
- NAP1L5 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs750607379, COSV99985826; called by muse, mutect2, varscan2
- NFKB1 | c.2698C>G p.Q900E (on ENST00000394820 / NM_001382627.1; = p.Q901E on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.071); catalogued as rs558088267, COSV99897664; called by muse, mutect2, varscan2
- P2RX4 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100243105; called by muse, mutect2, varscan2
- PATJ | c.2326G>C p.D776H | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs12141573, COSV100333860; called by muse, mutect2, varscan2
- PCDH11X | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs1489435124, COSV100013723; called by muse, mutect2
- PHF3 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as COSV100013720; called by muse, mutect2, varscan2
- PIP5K1A | c.349G>C p.E117Q (on ENST00000368888 / NM_001135638.2; = p.E104Q on NM_003557.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100576706; called by muse, mutect2, varscan2
- PLXNA4 | c.938C>G p.A313G | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100326025; called by muse, mutect2, varscan2
- PRPF19 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV99920714; called by muse, mutect2, varscan2
- RAPGEF2 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as rs779487803, COSV52424693; called by muse, mutect2, varscan2
- RBL1 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs757362982, COSV100727218; called by muse, mutect2, varscan2
- RGS22 | c.2091G>A p.W697* | Nonsense Mutation (SNP) | VAF 39/94 reads (41%) | catalogued as COSV100693590; called by muse, mutect2, varscan2
- RYR2 | c.9469G>T p.E3157* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100772064; called by muse, mutect2, varscan2
- SEMA3C | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs373225376; called by muse, mutect2, varscan2
- SLC4A2 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.867); catalogued as COSV100055651; called by muse, mutect2, varscan2
- SPATA18 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99730968; called by muse, mutect2, varscan2
- TBX5 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs867728273, COSV100091732, COSV59862447; called by muse, mutect2, varscan2
- TBX5 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100091734; called by muse, mutect2, varscan2
- TCEA1 | c.338T>A p.V113E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1337009716, COSV101124295, COSV67172500; called by muse, mutect2, varscan2
- TEX19 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100331066; called by muse, mutect2, varscan2
- TGFBR2 | c.1396+1G>A p.X466_splice | Splice Site (SNP) | VAF 61/103 reads (59%) | catalogued as rs528566980, COSV55460273; called by muse, mutect2, varscan2
- THBS2 | c.2420-2A>C p.X807_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100827995; called by muse, mutect2, varscan2
- THOC2 | c.2262C>G p.I754M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99833866; called by muse, mutect2, varscan2
- TIE1 | c.1413C>G p.F471L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV100992138; called by muse, mutect2, varscan2
- TRAV8-6 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs752047476; called by muse, mutect2, varscan2
- TSSK1B | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs375756830; called by muse, mutect2, varscan2
- TTN | c.912C>T p.V304= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100623063; called by muse, mutect2, varscan2
- WDR33 | c.3653C>T p.S1218F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV100205334; called by muse, mutect2, varscan2
- ZHX3 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58383675; called by muse, mutect2, varscan2
- ZNF275 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs782812244, COSV100936398; called by muse, mutect2, varscan2
- ZNF333 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.856); catalogued as COSV99469429; called by muse, mutect2, varscan2
- ZNF765 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101125532; called by muse, mutect2, varscan2
- CAPN3 | c.633-4_654delinsC p.X211_splice | Splice Site (DEL) | VAF 24/41 reads (59%) | called by pindel, varscan2*
- ITGB1BP1 | c.21_28del p.R8* | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- SYNE3 | c.258del p.L87* | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- ACTR5 | c.732G>A p.E244= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs1201845483, COSV99709929, COSV99710152; called by muse, mutect2, varscan2
- ATM | c.8166G>C p.L2722= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV53764129, COSV99590905; called by muse, mutect2, varscan2
- BEX4 | c.39C>T p.N13= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV65516042; called by muse, mutect2
- C16orf70 | c.1086G>A p.V362= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV99531553; called by muse, mutect2, varscan2
- CEP112 | c.1992G>A p.L664= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101211004; called by muse, mutect2, varscan2
- CKAP5 | c.1674G>A p.G558= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1467886705, COSV100371155; called by muse, mutect2, varscan2
- DDX17 | c.162C>T p.V54= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV99318869; called by muse, mutect2, varscan2
- EIF4A1 | c.525C>T p.Y175= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1404425225, COSV99549147; called by muse, mutect2
- EPHX4 | c.111C>T p.L37= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100952744; called by muse, varscan2
- GABRB3 | c.867C>A p.I289= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV100161067; called by muse, mutect2, varscan2
- GLB1 | c.649C>T p.L217= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100257579; called by muse, mutect2, varscan2
- HAL | c.1500C>T p.H500= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99701586; called by muse, mutect2, varscan2
- HTR4 | c.972C>A p.L324= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100089087, COSV58801843; called by muse, mutect2, varscan2
- LIG3 | c.2466T>C p.L822= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99252958; called by muse, mutect2, varscan2
- MAP9 | c.66T>A p.T22= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100251033; called by muse, mutect2, varscan2
- MTUS2 | c.1836G>A p.Q612= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV70916689; called by muse, mutect2, varscan2
- MUCL3 | c.1110C>T p.V370= (on ENST00000304311; = p.V1246= on NM_080870.4) | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100424069, COSV100424291; called by muse, mutect2, varscan2
- NOMO2 | c.87G>C p.A29= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100395753; called by muse, mutect2, varscan2
- NSMCE1 | c.657C>T p.Y219= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs371500174; called by muse, mutect2, varscan2
- PCDH17 | c.3192G>A p.L1064= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100931799; called by muse, mutect2, varscan2
- PCDHGA6 | c.2376G>A p.L792= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99543209; called by muse, mutect2, varscan2
- PTPN4 | c.2115C>A p.I705= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as COSV99750968; called by muse, mutect2
- RELT | c.564G>A p.R188= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99293034; called by muse, mutect2
- SERPINA4 | c.918G>A p.R306= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs866969383, COSV54068801; called by muse, mutect2, varscan2
- SLC12A3 | c.2613G>A p.R871= (on ENST00000563236 / NM_001126108.2; = p.R880= on NM_000339.3) | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99344555; called by muse, mutect2, varscan2
- SYNE1 | c.1275G>A p.L425= (on ENST00000367255 / NM_182961.4; = p.L432= on NM_033071.3) | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV55103193, COSV99573468; called by muse, mutect2, varscan2
- SYNGAP1 | c.216G>A p.R72= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99538772; called by muse, mutect2
- ZBBX | c.813C>T p.T271= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs375095384; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846171 del GCATACCAGGCCAGGAAAAAGGGCCTTGGTGATCA | 5'Flank (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- DNAJC11 | c.704+393G>A | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- ELMOD1 | c.-86+454C>T | Intron (SNP) | VAF 9/91 reads (10%) | catalogued as COSV99759556, COSV99760291; called by muse, mutect2
- RABGGTB | c.309+128G>A | Intron (SNP) | VAF 23/65 reads (35%) | catalogued as rs1240908025, COSV100175193; called by muse, mutect2, varscan2
- RUSC1 | c.-132G>A | 5'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99430138; called by mutect2, varscan2
- SNORD115-41 | n.34G>A | RNA (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
